Surgical pathology report (de-identified scan), TCGA case TCGA-DK-AA77, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-AA77-01A (Primary Tumor).

[page 1 of 5]
SURGICAL PATHOLOGY REPORT

Patient Name:

Accession #:

Med. Rec. #:

Date of Procedure:

DOB: (Age:

Location:

Date of Receipt:

Gender:

M

Service:

Urology

Date of Report:

Ref. Physician:

Account #:

Patient Address:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

HG T1 UC.

CLUE *ICD: O-3*
path (Carcinoma), urothelial NOS 8120/3
(Carcinoma) urothelial, papillary 8130/3
Site: Bladder, posterior wall C674
JW 4/30/14

Specimens Submitted:

- 1: Urethral margin (fs)
- 2: Right distal pelvic lymph nodes
- 3: Left distal pelvic lymph nodes
- 4: Bladder, prostate, seminal vesicles and peri-vesicle lymph nodes
- 5: Left distal ureter
- 6: Right distal ureter

DIAGNOSIS:

1. **Urethral margin (fs):**
- Benign prostatic tissue and urothelium
2. **Right distal pelvic lymph nodes:**
Lymph Node Dissection:
Benign lymph nodes
Number of lymph nodes examined: 18
3. **Left distal pelvic lymph nodes:**
Lymph Node Dissection:
Benign lymph nodes
Number of lymph nodes examined: 22
4. **Bladder, prostate, seminal vesicles and peri-vesicle lymph nodes:**
a.

Tumor Type:

Invasive urothelial carcinoma, NOS

Histologic Grade:

High grade

Pattern of growth of the Non-Invasive component:

Papillary and flat

Pattern of growth of the Invasive component:

Infiltrating

Tumor Multicentricity:

Identified

Bladder Local Invasion:

Superficial half of muscularis propria

Extravesical Tumor Extension:

Urethra uninvolved

Carcinoma in-situ present at right and left ureteral orifice, with focal lamina propria invasion at left ureteral orifice

Vascular Invasion:

Not identified

[page 2 of 5]
SURGICAL PATHOLOGY REPORT

Perineural Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Mucosa:

Exhibiting prior procedure-related changes

Prostate:

Other See 4b

Seminal Vesicles:

Not involved

Perivesical Lymph Nodes:

Not involved (0/1)

The Pathologic Stage is (AJCC 2002):

pT2a (Invades superficial half of muscularis propria)

PR0 (No involvement of prostate)

b.

Tumor Type:

Adenocarcinoma

Gleason's Grade:

Primary Gleason grade:3

Secondary Gleason grade:3

Total Gleason score:6

Tumor Location:

Involves Left posterior

Minute focus

Vascular Invasion:

Not Identified

Perineural Invasion:

Not identified

Tumor Multicentricity:

Not identified

High Grade Prostatic Intraepithelial Neoplasia:

Identified

Capsule:

Tumor confined to prostate

Seminal Vesicles:

Not involved

Bladder Neck:

Not Involved

Surgical Margins:

Free of tumor

Non-Neoplastic Prostate:

Unremarkable

Staging (AJCC 1997):

pT2a (confined to the prostate & capsule, involving one lobe)

5. Left distal ureter:

- Benign segment of ureter

6. Right distal ureter:

- Benign segment of ureter

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

[page 3 of 5]
Gross Description:

1) The specimen is received fresh for frozen section consultation, labeled "urethral margin" and consists of tissue measuring 1.3 x 1.0 x 0.3 cm. Entirely submitted for frozen section.

Summary of sections:

FSC1-1 -- frozen section control

2) The specimen is received fresh, labeled, "Right distal pelvic lymph nodes", and consists of a piece of tan-yellow fatty tissue measuring 7.0 x 3.0 x 2.0 cm. Sectioning reveals multiple tan-yellow fatty lymph nodes ranging from 0.4 to 2.2 cm in greatest dimension. The specimen is entirely submitted.

Summary of sections:

BLN1-6- bisected lymph nodes

MLN -- multiple lymph nodes

RT -- remaining tissue

3) The specimen is received fresh, labeled, "Left distal pelvic lymph nodes", and consists of a piece of tan-yellow fatty tissue measuring 7.0 x 5.0 x 2.0 cm. Sectioning reveals multiple tan-yellow fatty lymph nodes ranging from 0.1 to 2.5 cm in greatest dimension. The specimen is entirely submitted.

Summary of sections:

BLN1-4- bisected lymph nodes

MLN -- multiple lymph nodes

RT -- remaining tissue

4) The specimen is received fresh labeled, "Bladder, prostate, seminal vesicles, and peri-vesicle lymph nodes ". It consists of a bladder with attached bladder and adnexa measuring 16.5 cm from superior to inferior, 12.3 cm laterally and 4.3 cm from anterior to posterior. The anterior aspect of the bladder is inked black and the posterior blue. The prostatic urethral margin is shaved and submitted. The bladder is opened along the anterior midline to reveal a pink-tan papillary mass measuring 4.7 x 3.4 x 2.0 cm predominately on the left posterior wall. The lesion lies 0.5 cm from the left ureteral orifice and 1.5 from the right. Adjacent to the papillary mass is a 1.6 x 1.6 cm pink-tan scar lesion, which measures 0.1 cm from the left ureteral orifice, and 3.5 cm from the right. There is a 0.4 x 0.2 x 0.1 cm papillary area adjacent to the right ureteral orifice which measures 2.0 cm from the tumor. Both ureters are probe patent, measuring up to 0.2 cm in maximum diameter. Sectioning of the scar lesion reveals a tan cut which does not extend to the inked fat. The mass is sectioned to reveal a white- tan slightly irregular cut surface. Extension to the inked fat is grossly not identified. The remaining bladder mucosa is tan-pink with the normal folds. A perivesical lymph node is identified. The prostate is serially sectioned to reveal white-tan prostatic parenchyma. Representative sections are submitted including sections from each prostatic quadrant and transition zone. TPS is submitted. Gross photograph is taken.

Summary of sections:

UM - urethral margin

RUM - right ureter margin

LUM - left ureter margin

M--mass

SL--scar lesion (entirely submitted)

RUO - right ureter orifice (with papillary area)

LUO - left ureter orifice (with scar lesion)

LPW - left posterior wall

LAW - left anterior wall

RPW - right posterior wall

RAW - right anterior wall

TRI - trigone

DOM - dome

F - perivesical fat

[page 4 of 5]
SURGICAL PATHOLOGY REPORT

RSV - right seminal vesicle
LSV - left seminal vesicle
RAP - right apex prostate
LAP - left apex prostate
RAM - right anterior mid prostate
RPM - right posterior mid prostate
LAM - left anterior mid prostate
LPM - left posterior mid prostate
RAB - right anterior base prostate
RPB - right posterior base prostate
LAB - left anterior base prostate
LPB - left posterior base prostate
LN--lymph node

5) The specimen is received in formalin, labeled "Left distal ureter, unclipped end in the margin" and consists of a tan-white tubular tissue fragment measuring 3.3 cm in length and 1.2 cm in diameter, with attached adipose tissue measuring 1.1 cm in thickness. There is a clip at one end of the specimen. On cut section, the mucosa appears is tan-pink and unremarkable. The specimen is sequentially sectioned from the clipped end to the non-clipped end and submitted entirely.

Summary of sections:

CE - clipped end

NCE - non-clipped end

SS - sequential sections from clipped to non-clipped end

6) The specimen is received in formalin, labeled "Right distal ureter, unclipped ended margin" and consists of a tan-white tubular tissue fragment measuring 5.0 cm in length and 1.0 cm in diameter, with attached adipose tissue measuring 1.3 cm in thickness. There is a clip at one end of the specimen. On cut section, the mucosa appears tan-pink and unremarkable. The specimen is sequentially sectioned from the clipped end to the non-clipped end and submitted entirely.

Summary of sections:

CE - clipped end

NCE - non-clipped end

SS - sequential sections from clipped to non-clipped end

Summary of Sections:

Part 1: Urethral margin (fs)

Blocks	Block Designation	PCs
1	{not entered}	

Part 2: Right distal pelvic lymph nodes

Blocks	Block Designation	PCs
2	BLN1	2
1	BLN2	2
1	BLN3	2
1	BLN4	2
1	BLN5	2
1	BLN6	2
2	MLN	10
4	RT	4

Part 3: Left distal pelvic lymph nodes

Blocks	Block Designation	PCs
2	BLN1	2
1	BLN2	2
1	BLN3	2
1	BLN4	2
3	MLN	12

[page 5 of 5]
SURGICAL PATHOLOGY REPORT

9 RT 9

Part 4: Bladder, prostate, seminal vesicles and peri-vesicle lymph nodes

Blocks	Block Designation	PCs
1	DOM	2
1	F	2
1	LAB	1
1	LAM	1
1	LAP	1
1	LAW	2
1	LN	1
1	LPB	1
1	LPM	1
1	LPW	2
1	LSV	1
1	LUM	1
1	LUO	1
4	M	4
1	RAB	1
1	RAM	1
1	RAP	1
1	RAW	2
1	RPB	1
1	RPM	1
1	RPW	2
1	RSV	1
1	RUM	1
1	RUO	1
4	SL	4
1	TRI	2
1	UM	1

Part 5: Left distal ureter

Blocks	Block Designation	PCs
1	CE	1
1	NCE	1
2	SS	5

Part 6: Right distal ureter

Blocks	Block Designation	PCs
1	CE	1
1	NCE	1
3	SS	6

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen Section Diagnosis: Urethral margin (fs): Benign ()
Permanent Diagnosis: Same

Criteria	W 2/13/14	Yes	No

Source: NCI Genomic Data Commons file 3bf7a4dc-6663-477c-bbe1-2cc5d7ad2b30 (TCGA-DK-AA77.382A39E0-F94D-4828-8B30-22A4080724BB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).